Somatic mutation profile of tumor specimen C3L-02350-02 (aliquot CPT0104750009) from CPTAC case C3L-02350, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.5 years (25,374 days).
Specimen C3L-02350-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db051d09-b184-4580-8525-1378ea1684a1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02350-31 (Blood Derived Normal), aliquot CPT0105180002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4682745d-a518-4358-855c-89a10b33d7e2

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 6 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 6, Nonsense Mutation 3, 3'UTR 3, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 2, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALG13 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV52644769; called by muse, mutect2, varscan2
- FCRL3 | c.1133-6C>T | Splice Region (SNP) | VAF 6/52 reads (12%) | catalogued as COSV63844299; called by muse, mutect2, varscan2
- GLDC | c.1952A>C p.H651P | Missense Mutation (SNP) | VAF 59/502 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM061025; called by muse, mutect2, varscan2
- GUCY2D | c.1519G>A p.V507M | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs746002871, COSV99644422; called by muse, mutect2
- LCE2D | c.268G>A p.D90N | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.055); catalogued as rs753899892, COSV64228947, COSV64229148; called by muse, mutect2
- LRP1B | c.11009G>T p.G3670V | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.452); catalogued as COSV67191244; called by muse, mutect2, varscan2
- METTL25 | c.1385G>C p.R462P | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50257586; called by muse, mutect2
- PPM1E | c.2035C>T p.H679Y | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs764019992, COSV57571359; called by muse, mutect2, varscan2
- RYR1 | c.12571C>A p.R4191S | Missense Mutation (SNP) | VAF 9/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV62107633; called by muse, mutect2
- SLC8A3 | c.2684G>A p.R895H (on ENST00000381269 / NM_183002.3; = p.R893H on NM_033262.4) | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as rs372909057; called by muse, mutect2
- SS18L1 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 74/383 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV100064999; called by muse, mutect2, varscan2
- TWIST1 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT tolerated (0.38); PolyPhen benign (0.05); catalogued as rs200605809; called by muse, mutect2
- ABCB4 | c.1715A>C p.Q572P | Missense Mutation (SNP) | VAF 57/413 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ATP2A2 | c.185T>G p.V62G | Missense Mutation (SNP) | VAF 25/421 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- FAM200B | c.1610T>C p.V537A | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); called by muse, mutect2
- FASN | c.1148T>C p.V383A | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.209); called by muse, mutect2
- FLNA | c.361dup p.L121Pfs*41 | Frame Shift Ins (INS) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- GRM7 | c.1501_1502del p.E501Tfs*12 | Frame Shift Del (DEL) | VAF 27/187 reads (14%) | called by mutect2, pindel, varscan2
- HDAC9 | c.914C>A p.S305* | Nonsense Mutation (SNP) | VAF 14/118 reads (12%) | called by muse, mutect2, varscan2
- IL36G | c.487T>C p.F163L | Missense Mutation (SNP) | VAF 25/152 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- KCNN2 | c.1652T>C p.V551A (on ENST00000264773; = p.V763A on NM_021614.4) | Missense Mutation (SNP) | VAF 50/384 reads (13%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- MBD1 | c.677G>C p.G226A | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOC4L | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- OR2B11 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 23/238 reads (10%) | SIFT tolerated (0.58); PolyPhen benign (0.138); called by muse, mutect2
- ORC4 | c.1226C>T p.T409I | Missense Mutation (SNP) | VAF 13/336 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.054); called by muse, mutect2
- PCDH15 | c.1172A>T p.Q391L | Missense Mutation (SNP) | VAF 72/472 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- PHC1 | c.2420C>T p.A807V | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.207); called by muse, mutect2
- PLPPR4 | c.1092C>A p.S364R | Missense Mutation (SNP) | VAF 16/379 reads (4%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.729); called by muse, mutect2
- PLS3 | c.1432del p.L478Wfs*9 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | called by mutect2, pindel, varscan2
- PPBP | c.12A>T p.R4S | Missense Mutation (SNP) | VAF 33/186 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- PRG4 | c.2783C>T p.P928L | Missense Mutation (SNP) | VAF 24/574 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.217); called by muse, mutect2
- PXDN | c.2243G>A p.C748Y | Missense Mutation (SNP) | VAF 9/251 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RFX6 | c.2111A>G p.Q704R | Missense Mutation (SNP) | VAF 35/347 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RNF20 | c.2754dup p.R919Tfs*8 | Frame Shift Ins (INS) | VAF 7/61 reads (11%) | called by mutect2, pindel
- RSPH6A | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 57/435 reads (13%) | called by muse, mutect2, varscan2
- SFTPD | c.494A>T p.K165M | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SNRNP200 | c.6188G>T p.G2063V | Missense Mutation (SNP) | VAF 46/532 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); called by muse, mutect2
- SOS1 | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 46/313 reads (15%) | called by muse, mutect2, varscan2
- ST6GALNAC2 | c.774-7G>A | Splice Region (SNP) | VAF 34/248 reads (14%) | called by muse, mutect2, varscan2
- STAG2 | c.1711C>G p.L571V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- TESPA1 | c.1184T>C p.L395P (on ENST00000316577 / NM_001098815.3; = p.L257P on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- USP26 | c.547A>G p.M183V | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- ZNF335 | c.2442G>C p.Q814H | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ZNF335 | c.2388G>C p.L796F | Missense Mutation (SNP) | VAF 142/362 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, varscan2
- ZNF784 | c.37_41del p.S13Dfs*17 | Frame Shift Del (DEL) | VAF 12/134 reads (9%) | called by mutect2, pindel
- EMILIN3 | c.1230G>A p.R410= | Silent (SNP) | VAF 13/111 reads (12%) | called by muse, mutect2, varscan2
- MROH8 | c.1404C>T p.F468= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV54124852; called by muse, mutect2, varscan2
- PLCD3 | c.201G>A p.R67= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as COSV59561310; called by muse, mutect2, varscan2
- SLC46A1 | c.681T>G p.A227= | Silent (SNP) | VAF 35/301 reads (12%) | called by muse, mutect2, varscan2
- SPATA31A7 | c.972C>G p.G324= | Silent (SNP) | VAF 14/108 reads (13%) | called by mutect2, varscan2
- ZNF543 | c.105G>A p.Q35= | Silent (SNP) | VAF 22/187 reads (12%) | called by muse, mutect2, varscan2
- ARSJ | c.*89A>G | 3'UTR (SNP) | VAF 25/242 reads (10%) | catalogued as COSV59540325; called by muse, mutect2, varscan2
- DCAF17 | c.*3031T>G | 3'UTR (SNP) | VAF 14/123 reads (11%) | called by muse, mutect2, varscan2
- RPL7P3 | chr20:62570578 G>T | 5'Flank (SNP) | VAF 86/427 reads (20%) | called by muse, mutect2, varscan2
- SELENBP1 | c.-27C>G | 5'UTR (SNP) | VAF 16/225 reads (7%) | catalogued as COSV100923661, COSV99057098; called by muse, mutect2
- UTP20 | c.*18A>C | 3'UTR (SNP) | VAF 22/167 reads (13%) | catalogued as COSV99880520; called by muse, mutect2, varscan2
